Surgical pathology report (de-identified scan), TCGA case TCGA-BA-6870, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site UNC, specimen TCGA-BA-6870-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY

Case Number : [REDACTED]

Diagnosis:

A: Right pyriform sinus, biopsy

- Squamous mucosa with focal moderate dysplasia and intraepithelial chronic inflammation
- No invasive carcinoma identified.

B: Cervical esophagus, biopsy

- Superficial tangential fragments of benign squamous mucosa.

C: Larynx, right supraglottic region, biopsy

- Invasive squamous cell carcinoma, moderately differentiated, with cartilaginous invasion.

D: Tongue, right tongue base, biopsy

- Squamous mucosa with focal moderate dysplasia
- No invasive carcinoma identified.

Clinical History:

The patient is a [REDACTED] with a history of supraglottic lary [REDACTED] going diagnostic bronchoscopy and esophagoscopy with direct laryngoscopy.

Gross Description:

Received are four appropriately labeled containers.

Container A is also labeled "right pyriform sinus". The container holds a thin strip of white-tan soft tissue measuring 2 x 0.4 x 0.1 cm. The specimen is totally submitted in A1, [REDACTED]

Container B is also labeled "cervical esophagus". It holds one minute white-tan soft tissue fragment measuring 0.1 x 0.1 x 0.1 cm. The specimen is totally submitted in B1, [REDACTED]

Container C is additionally labeled "right supraglottic larynx". It holds multiple white-tan and hemorrhagic soft tissue fragments measuring in aggregate 2.9 x 2.7 x 0.9 cm.

[page 2 of 2]
The specimen is totally submitted in C1 and C2, [REDACTED]

Container D is additionally labeled "right tongue base". It holds multiple white-tan and hemorrhagic soft tissue fragments measuring in aggregate 1.1 x 0.8 x 0.6 cm. The specimen is totally submitted in D1, [REDACTED]

Light Microscopy:

Light microscopic examination is performed by Dr.

Source: NCI Genomic Data Commons file 819c5254-c4b1-4133-9b57-37ca6ac15257 (TCGA-BA-6870.8D486D6F-29F4-42DF-89A9-E51168638BC9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).